TCGA case TCGA-IR-A3LB — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e7c7783c-1d0f-4f42-a4cf-518825e91d91

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 2,032 days (5.6 years).

Diagnoses (2)
1. Adenocarcinoma, endocervical type (the primary disease): ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 53.0 years (19,374 days); Year of diagnosis: 2002; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 29; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 72 days; Days to treatment end: 138 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 72 days; Days to treatment end: 141 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 72 days; Days to treatment end: 118 days; Treatment dose: 5,040 cGy; Treatment outcome: Complete Response; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 363 days; Days to treatment end: 500 days (1.4 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 4; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Prescribed dose: 70; Prescribed dose units: mg/m2; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Number of cycles: 4; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Prescribed dose: 1000; Prescribed dose units: mg/m2; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 5,040 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 0 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Lymph Node(s) Paraaortic.
2. Metastasis of diagnosis 1 (Adenocarcinoma, endocervical type), site: Lung, NOS. Age at diagnosis: 53.9 years (19,691 days); Days to diagnosis: 317 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (2 entries)
- Day 317 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 317 days; Evidence of progression type: Histologic Confirmation.
- Days to follow up: 2,032 days (5.6 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94 kg; Height: 168 cm; BMI: 33.3.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2.5; Tobacco smoking quit year: 1972; Age at onset: 17.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IR-A3LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-IR-A3LB-01A-01-TSA: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IR-A3LB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IR-A3LB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Total pregnancy count: 4; Tobacco smoking history indicator: 3; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy type: Radical trachelectomy; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 0.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 1: Chemo concurrent dose: 70mg/m2; Chemo concurrent fractions total: 4.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 2: Chemo concurrent type other: Fluorouracil (5-FU); Chemo concurrent dose: 1000mg/m2; Chemo concurrent fractions total: 4.
- Drug treatment 2: Pharmaceutical therapy drug name: Fluorouracil (5-FU).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,032 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,032 days; disease-free interval: event (new tumor event after initially disease-free), 317 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 317 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IR-A3LB-01A-11D-A242-01): tumor purity 0.72, ploidy 1.8, whole-genome doublings 0.
